Somatic mutation profile of tumor specimen 0DEV4Q from CCDI case PBBRJW, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 16.2 years (5,925 days).
Specimen 0DEV4Q: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 60d0ce0f-22b1-43f4-9b1d-6b10ecd8f2ba.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DEV2F (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3cc6d0fa-5935-430b-a929-ea3b4c479738

The open-access MAF lists 9 somatic variants for this specimen: 5 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Silent 2, 3'UTR 1, Intron 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 102/295 reads (35%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen benign (0.083); catalogued as rs121913238, COSV55502066, COSV55502677; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TRPV6 | c.86G>A p.R29Q | Missense Mutation (SNP) | VAF 26/125 reads (21%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0); catalogued as rs374525154; called by muse, mutect2, varscan2
- DHRS12 | c.447G>A p.L149= (on ENST00000444610 / NM_001377930.1; = p.L100= on NM_024705.2 and 2 other RefSeq transcripts) | Splice Region (SNP) | VAF 61/207 reads (29%) | called by muse, mutect2, varscan2
- HNRNPU | c.307C>G p.Q103E | Missense Mutation (SNP) | VAF 29/158 reads (18%) | SIFT tolerated (1); PolyPhen possibly damaging (0.76); called by muse, mutect2, varscan2
- TTLL2 | c.452C>T p.T151I | Missense Mutation (SNP) | VAF 13/395 reads (3%) | SIFT tolerated (0.22); PolyPhen benign (0.013); called by muse, mutect2
- KRAS | c.180T>A p.G60= | Silent (SNP) | VAF 104/297 reads (35%) | catalogued as rs397517037, COSV55499291, COSV55523567, COSV99782811; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RELN | c.4848G>A p.L1616= | Silent (SNP) | VAF 30/366 reads (8%) | catalogued as rs200733882; called by muse, mutect2
- IQCE | c.1969+100G>A | Intron (SNP) | VAF 83/269 reads (31%) | catalogued as rs545905471; called by muse, mutect2, varscan2
- OR12D3 | c.*27T>C | 3'UTR (SNP) | VAF 14/284 reads (5%) | called by muse, mutect2
